Gene-level copy-number profile of tumor specimen C3N-03785-03 from CPTAC case C3N-03785, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.3 years (24,203 days).
Specimen C3N-03785-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d0a10f89-d828-4dc5-b804-bb165a91d919.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03785-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/6b49bead-e37c-4195-919f-18b8a99681c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 627; copy number 1: 16,075; copy number 2: 35,174; copy number 3: 6,089; copy number 4: 758; copy number 5: 70; copy number 7: 18; copy number 13: 3; copy number 16: 6; copy number 17: 11; copy number 19: 32; copy number 21: 16.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr3:11,488,300–11,529,755, 2 genes (within-gene range 0–2): AC026185.1, AC022001.1.
- chr3:58,162,547–58,170,636, 1 gene (within-gene range 0–2): FLNB-AS1.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:121,164,687–121,671,872, 6 genes: AC008568.1, AC010350.1, AC008568.2, RPL23AP44, AC106806.1, AC106806.2.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,892,188–22,128,103, 10 genes (within-gene range 0–1): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:87,008,440–87,042,419, 2 genes: AL513318.1, CDC20P1.
- chr11:71,903,194–71,997,597, 3 genes (within-gene range 0–1): OR7E126P, RNF121, AP002490.2.
- chr12:18,683,169–20,370,262, 23 genes (within-gene range 0–1): PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468, AC129102.1.
- chr12:20,449,655–20,450,083, 1 gene (within-gene range 0–1): UBE2L2.
- chr13:66,218,250–70,459,570, 33 genes: MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, BCRP9, NPM1P22, OR7E111P, OR7E33P, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P.
- chr17:55,842,677–56,511,659, 4 genes (within-gene range 0–2): AC090618.1, ANKFN1, AC006600.1, AC006600.2.
- chr21:8,603,547–8,680,934, 2 genes: RPSAP68, CR381572.2.
- chr21:9,053,122–9,129,752, 4 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 156 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,111,815–16,352,480, 58 genes, copy number 5 (within-gene range 3–5): TMEM51-AS1, TMEM51, C1orf195, MFFP1, ZBTB2P1, FHAD1, FHAD1-AS1, AL031283.2, AL031283.1, EFHD2, CTRC, CELA2A, CELA2B, CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, CPLANE2, MT1XP1, FBXO42.
- chr11:68,261,338–71,252,577, 68 genes, copy number 13–21 (broad region; genes not listed).
- chr16:33,495,943–33,875,468, 18 genes, copy number 7: AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3, AC142384.1, BMS1P8, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3.
- chr21:26,158,091–26,967,088, 12 genes, copy number 5 (within-gene range 4–5): AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759.

Autosomal genes at a single copy (total copy number 1): 13,734. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
